Somatic mutation profile of tumor specimen TCGA-AZ-6603-01A (aliquot TCGA-AZ-6603-01A-11D-1835-10) from TCGA case TCGA-AZ-6603, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; Age at diagnosis: 77.8 years (28,424 days).
Specimen TCGA-AZ-6603-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b6ae483c-aa7c-4670-b40e-04f8e12256bf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AZ-6603-11A (Solid Tissue Normal), aliquot TCGA-AZ-6603-11A-02D-1835-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cf6aaf01-e283-40f3-8dfc-3365bcba8929

The open-access MAF lists 81 somatic variants for this specimen: 66 protein-altering or splice-affecting, 14 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 57, Silent 14, Frame Shift Del 4, Splice Region 2, In Frame Del 1, Frame Shift Ins 1, Intron 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.396G>T p.K132N | Missense Mutation (SNP) | VAF 7/16 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs866775781, COSV52688381, COSV52705927, COSV52891203, COSV53339296; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ABCA8 | c.3383del p.L1128* | Frame Shift Del (DEL) | VAF 18/72 reads (25%) | catalogued as COSV52209897; called by pindel, varscan2
- ADAMTS15 | c.1360G>A p.V454M | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs535808287, COSV100143032, COSV54509533; called by muse, mutect2, varscan2
- ALOX15B | c.1200G>A p.K400= | Splice Region (SNP) | VAF 4/37 reads (11%) | catalogued as COSV101205656; called by muse, mutect2
- ARHGAP5 | c.1465G>A p.E489K | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.689); catalogued as rs78337553, COSV61533654; called by muse, mutect2, varscan2
- ATP8B3 | c.3553T>C p.S1185P | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.462); catalogued as COSV100034701; called by muse, mutect2, varscan2
- CDK1 | c.26A>G p.K9R | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV57350392; called by muse, mutect2, varscan2
- CDK5RAP1 | c.799G>A p.V267I | Missense Mutation (SNP) | VAF 90/119 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59428889; called by muse, mutect2, varscan2
- COL6A3 | c.3197G>A p.R1066H | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs768971873, COSV55108525; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CRISPLD1 | c.305G>T p.S102I | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as COSV51552927; called by muse, mutect2, varscan2
- CUBN | c.6670C>A p.H2224N | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.36); PolyPhen benign (0.023); catalogued as rs1209320744, COSV64726681; called by muse, mutect2, varscan2
- DLGAP5 | c.1271C>T p.A424V | Missense Mutation (SNP) | VAF 122/182 reads (67%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV55965246; called by muse, mutect2, varscan2
- DSCAM | c.5902G>A p.V1968M | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.127); catalogued as rs746017443, COSV68035652; called by muse, mutect2, varscan2
- FAM227B | c.226C>T p.R76* | Nonsense Mutation (SNP) | VAF 51/142 reads (36%) | catalogued as rs905733396, COSV100175471, COSV54814391; called by muse, mutect2, varscan2
- FAM9A | c.65C>T p.T22M | Missense Mutation (SNP) | VAF 159/254 reads (63%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.011); catalogued as rs763112096, COSV66813237; called by muse, mutect2, varscan2
- FCRL5 | c.1694G>A p.R565H | Missense Mutation (SNP) | VAF 17/26 reads (65%) | SIFT tolerated (0.15); PolyPhen benign (0.38); catalogued as rs376321602, COSV62516000, COSV62519878; called by muse, mutect2, varscan2
- FMO5 | c.812G>C p.G271A | Missense Mutation (SNP) | VAF 40/90 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.936); catalogued as COSV54210307; called by muse, mutect2, varscan2
- FOXRED2 | c.445G>A p.V149I | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT tolerated (0.52); PolyPhen benign (0.311); catalogued as COSV53401545; called by muse, mutect2, varscan2
- GABRR3 | c.413A>T p.K138M | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101512319; called by muse, mutect2, varscan2
- GCDH | c.782C>G p.T261R | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV53368547; called by muse, mutect2, varscan2
- GMEB1 | c.1156G>T p.A386S | Missense Mutation (SNP) | VAF 30/113 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.33); catalogued as COSV53796630; called by muse, mutect2, varscan2
- GPR139 | c.476C>T p.T159I | Missense Mutation (SNP) | VAF 66/137 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV58504913; called by muse, mutect2, varscan2
- GPR158 | c.1228G>A p.V410I | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT tolerated (0.31); PolyPhen benign (0.206); catalogued as rs757293544, COSV66267946; called by muse, mutect2, varscan2
- GRIN3A | c.478G>T p.D160Y | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV62450125, COSV62452376, COSV62457978; called by muse, mutect2, varscan2
- HELB | c.1195G>A p.D399N | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.111); catalogued as rs1012792797, COSV56073807, COSV56075434; called by muse, mutect2, varscan2
- HTR1A | c.649C>T p.R217C | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1406728369, COSV100109187; called by muse, mutect2
- ITGAX | c.370G>A p.G124R | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs150827519; called by muse, mutect2, varscan2
- ITIH6 | c.3632G>A p.R1211Q | Missense Mutation (SNP) | VAF 18/119 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0.006); catalogued as rs535285789, COSV54494346; called by muse, mutect2, varscan2
- KIAA1109 | c.8589T>C p.F2863= | Splice Region (SNP) | VAF 21/90 reads (23%) | catalogued as COSV52691112; called by muse, mutect2, varscan2
- LOXL1 | c.1190C>T p.A397V | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs199938623, COSV56096181; called by muse, mutect2, varscan2
- LRRC36 | c.926A>C p.K309T | Missense Mutation (SNP) | VAF 20/131 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.943); catalogued as COSV52082193; called by muse, mutect2, varscan2
- MGAM | c.1847C>T p.A616V | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.294); catalogued as rs372476876, COSV72073881; called by muse, mutect2, varscan2
- MTA1 | c.1954G>A p.D652N | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); catalogued as COSV100231719; called by muse, mutect2
- MUC6 | c.3691G>A p.G1231R | Missense Mutation (SNP) | VAF 98/162 reads (60%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs765595248, COSV70149666; called by muse, mutect2, varscan2
- NUPR1 | c.133C>G p.R45G | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100257219; called by muse, mutect2, varscan2
- OR5H6 | c.842C>T p.P281L (on ENST00000642105; = p.P265L on NM_001005479.2) | Missense Mutation (SNP) | VAF 51/129 reads (40%) | SIFT tolerated (0.4); PolyPhen benign (0.009); catalogued as rs200721570, COSV67350961; called by muse, mutect2, varscan2
- OR7C1 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as rs766648649, COSV50183885; called by muse, varscan2
- PCDHGA5 | c.2122G>A p.V708I | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.083); catalogued as COSV54026839; called by muse, mutect2, varscan2
- PDCL | c.857G>A p.R286H | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as rs1427822305, COSV99414164, COSV99414165; called by muse, mutect2
- PDGFRB | c.3293G>A p.R1098Q | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); catalogued as rs151236133; called by muse, mutect2, varscan2
- PIGO | c.2054G>A p.R685H | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT tolerated (0.11); PolyPhen benign (0.269); catalogued as rs537260013, COSV53055365; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PITPNM1 | c.439G>A p.A147T | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.464); catalogued as COSV100039439; called by muse, mutect2, varscan2
- PNMA3 | c.1051G>A p.E351K | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.62); PolyPhen benign (0.127); catalogued as COSV64722963; called by muse, mutect2, varscan2
- POT1 | c.1242A>T p.Q414H | Missense Mutation (SNP) | VAF 13/119 reads (11%) | SIFT tolerated (0.42); PolyPhen benign (0.005); catalogued as COSV62934499; called by muse, mutect2, varscan2
- PPP2R5D | c.406C>T p.L136F | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV57841437; called by muse, mutect2, varscan2
- PTPN1 | c.1250C>T p.T417M | Missense Mutation (SNP) | VAF 22/109 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); catalogued as rs922314694, COSV50403403; called by muse, mutect2, varscan2
- RBP3 | c.2324C>T p.T775M | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs201724324; called by muse, mutect2, varscan2
- RYR1 | c.4027G>A p.E1343K | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT tolerated (0.13); PolyPhen benign (0.178); catalogued as rs956750749, COSV62110079; called by muse, varscan2
- SEL1L3 | c.3016G>A p.D1006N | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.07); catalogued as rs942290602, COSV53549164; called by muse, mutect2, varscan2
- SLC24A2 | c.560C>T p.P187L | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53875742, COSV99645996; called by muse, mutect2, varscan2
- SMTNL2 | c.1075G>A p.E359K (on ENST00000389313 / NM_001114974.2; = p.E215K on NM_198501.3) | Missense Mutation (SNP) | VAF 28/48 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs367785658, COSV58809925; called by muse, mutect2, varscan2
- TENT5C | c.758G>A p.R253Q | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs779467652, COSV101033189, COSV65616833; called by muse, mutect2, varscan2
- TMCO3 | c.412C>T p.R138C | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1272910223, COSV64809198; called by muse, mutect2
- TSSK3 | c.86C>A p.S29Y | Missense Mutation (SNP) | VAF 49/86 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.241); catalogued as rs1214952089, COSV100344920; called by muse, mutect2, varscan2
- TTN | c.68924G>A p.R22975Q (on ENST00000591111; = p.R15551Q on NM_003319.4) | Missense Mutation (SNP) | VAF 46/97 reads (47%) | PolyPhen possibly damaging (0.786); catalogued as rs201694149, COSV100621370; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UBE3A | c.2462G>T p.G821V | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.966); catalogued as COSV51670426, COSV99216764; called by muse, mutect2, varscan2
- UGGT2 | c.2227C>T p.L743F | Missense Mutation (SNP) | VAF 215/431 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV65073510; called by muse, mutect2, varscan2
- YTHDC1 | c.2069C>G p.P690R (on ENST00000344157 / NM_001031732.4; = p.P672R on NM_133370.4) | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.987); catalogued as COSV60011997; called by muse, mutect2, varscan2
- ZSCAN29 | c.793T>C p.F265L | Missense Mutation (SNP) | VAF 30/59 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0.022); catalogued as COSV53021315; called by muse, mutect2, varscan2
- ZXDB | c.2008G>A p.D670N | Missense Mutation (SNP) | VAF 26/195 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV66492936; called by muse, mutect2, varscan2
- APC | c.472del p.Y158Ifs*12 | Frame Shift Del (DEL) | VAF 75/142 reads (53%) | called by mutect2, pindel, varscan2
- CDON | c.1433_1440del p.S478Wfs*25 | Frame Shift Del (DEL) | VAF 23/43 reads (53%) | called by mutect2, pindel, varscan2
- HADHA | c.445_447del p.G149del | In Frame Del (DEL) | VAF 26/83 reads (31%) | called by pindel, varscan2
- INPP5F | c.1449del p.K483Nfs*2 | Frame Shift Del (DEL) | VAF 10/61 reads (16%) | called by mutect2, pindel, varscan2
- PYHIN1 | c.125A>G p.E42G | Missense Mutation (SNP) | VAF 10/160 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2
- RFC4 | c.1073dup p.L359Vfs*8 | Frame Shift Ins (INS) | VAF 21/64 reads (33%) | called by mutect2, pindel, varscan2
- CASP2 | c.1062G>A p.P354= | Silent (SNP) | VAF 8/78 reads (10%) | catalogued as rs561597102, COSV60083483; called by mutect2, varscan2
- CCT6B | c.870C>T p.V290= | Silent (SNP) | VAF 21/170 reads (12%) | catalogued as rs375050990; called by muse, mutect2, varscan2
- DLGAP2 | c.1215G>A p.P405= | Silent (SNP) | VAF 14/26 reads (54%) | catalogued as rs373198112; called by muse, mutect2, varscan2
- FBN1 | c.2400T>C p.P800= | Silent (SNP) | VAF 31/132 reads (23%) | catalogued as COSV57329566; called by muse, mutect2, varscan2
- GRM6 | c.2205C>T p.P735= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as rs147912967; called by muse, mutect2, varscan2
- MAB21L2 | c.867G>A p.T289= | Silent (SNP) | VAF 11/43 reads (26%) | catalogued as COSV58263516; called by muse, mutect2, varscan2
- PCDH15 | c.1701C>T p.I567= | Silent (SNP) | VAF 75/182 reads (41%) | catalogued as rs773444573, COSV57288259; called by muse, mutect2, varscan2
- PCNX3 | c.5736C>T p.P1912= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as rs1179970606, COSV100856525; called by muse, mutect2
- POU4F3 | c.1005G>A p.S335= | Silent (SNP) | VAF 31/40 reads (78%) | catalogued as COSV57944955; called by muse, mutect2, varscan2
- SND1 | c.1254G>A p.T418= | Silent (SNP) | VAF 9/60 reads (15%) | catalogued as rs751946216, COSV61248621; called by muse, mutect2, varscan2
- TNFSF15 | c.585C>T p.L195= | Silent (SNP) | VAF 45/204 reads (22%) | catalogued as COSV65010066, COSV65010964; called by muse, mutect2, varscan2
- TUBA3C | c.688C>T p.L230= | Silent (SNP) | VAF 23/207 reads (11%) | catalogued as rs746581229, COSV67139952; called by muse, mutect2, varscan2
- ZBTB33 | c.1056T>C p.N352= | Silent (SNP) | VAF 9/79 reads (11%) | catalogued as COSV58535046; called by muse, mutect2, varscan2
- ZNF184 | c.1632T>G p.S544= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as COSV99279868; called by muse, mutect2
- SYNE2 | c.19333+876C>T | Intron (SNP) | VAF 12/16 reads (75%) | catalogued as rs762635611, COSV59943997; ClinVar: uncertain significance; called by muse, mutect2, varscan2
